Somatic mutation profile of tumor specimen TCGA-EJ-A65J-01A (aliquot TCGA-EJ-A65J-01A-11D-A30X-08) from TCGA case TCGA-EJ-A65J, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.7 years (22,904 days).
Specimen TCGA-EJ-A65J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0691c02c-6b45-4100-8823-3793c2df1f4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A65J-10A (Blood Derived Normal), aliquot TCGA-EJ-A65J-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f5442b4-8c91-43c1-9783-4a4634436eea

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO2 | c.1216A>T p.M406L (on ENST00000356134 / NM_001278597.3; = p.M410L on NM_001278596.3) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV59030984; called by muse, mutect2, varscan2
- AQR | c.4102A>T p.M1368L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV50039556; called by muse, mutect2, varscan2
- BCLAF3 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV61414313; called by muse, mutect2, varscan2
- CSMD1 | c.8962G>A p.G2988R (on ENST00000520002; = p.G2987R on NM_033225.6) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59344796; called by muse, mutect2, varscan2
- DHX40 | c.2204G>C p.G735A | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV52068601; called by muse, mutect2, varscan2
- F13A1 | c.863T>A p.V288D | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV53561719, COSV99343228; called by muse, mutect2, varscan2
- GAB2 | c.1332C>G p.D444E (on ENST00000361507 / NM_080491.3; = p.D406E on NM_012296.3) | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV60869125; called by muse, mutect2, varscan2
- GZMK | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV50245941; called by muse, mutect2, varscan2
- IFT140 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV63698288; called by muse, mutect2, varscan2
- ITGA9 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53246614; called by muse, mutect2, varscan2
- KCNA3 | c.1208T>G p.F403C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871193, COSV63902067; called by muse, mutect2, varscan2
- LONP2 | c.816G>T p.M272I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53523744; called by muse, mutect2, varscan2
- NPLOC4 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV58617289; called by muse, mutect2, varscan2
- RBKS | c.945dup p.D316Rfs*31 | Frame Shift Ins (INS) | VAF 32/100 reads (32%) | catalogued as rs746890274; called by mutect2, pindel, varscan2
- RGS21 | c.262A>C p.I88L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.212); catalogued as COSV69883006; called by muse, mutect2, varscan2
- SIX2 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs761435514, COSV57389851; called by muse, mutect2, varscan2
- SSRP1 | c.2045G>A p.R682K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1385847534, COSV53480313; called by muse, mutect2, varscan2
- TINAG | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52511681; called by muse, mutect2, varscan2
- TRAPPC11 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as rs1197120745, COSV58217444; called by muse, mutect2, varscan2
- TRPM3 | c.1816G>A p.D606N (on ENST00000357533 / NM_001366142.2; = p.D449N on NM_020952.6) | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV62589349; called by muse, mutect2, varscan2
- XRN1 | c.769T>A p.Y257N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53814280; called by muse, mutect2, varscan2
- ZNF536 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62827766; called by muse, mutect2, varscan2
- ZNF563 | c.199A>C p.M67L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53371134; called by muse, mutect2, varscan2
- POTEF | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); called by muse, mutect2
- ZFHX3 | c.5699_5700dup p.G1901Rfs*14 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- FBLN2 | c.1860C>T p.C620= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as COSV55487343; called by muse, mutect2, varscan2
- IGKV1D-8 | c.321T>A p.T107= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs779630886; called by muse, mutect2
- IRGQ | c.72C>T p.I24= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV60670983, COSV60671165; called by muse, mutect2, varscan2
- LSR | c.802C>T p.L268= (on ENST00000361790; = p.L249= on NM_015925.6) | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV61555509; called by muse, mutect2, varscan2
- PLIN5 | c.1065C>T p.H355= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs779314379, COSV67850820; called by muse, mutect2, varscan2
- SLC6A16 | c.1507C>T p.L503= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV60028740; called by muse, mutect2, varscan2
- SQOR | c.810A>G p.K270= | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as COSV52942479; called by muse, mutect2, varscan2
- TAF6L | c.1431A>T p.A477= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV53669714; called by muse, mutect2
- ZSCAN5A | c.1245C>T p.D415= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs761935616, COSV54226984; called by muse, mutect2, varscan2
- LINC01565 | n.998C>T | RNA (SNP) | VAF 16/46 reads (35%) | catalogued as rs761811536; called by muse, mutect2, varscan2
